Gene-level copy-number profile of tumor specimen ALCH-B26Q-TTP1-A from ALCHEMIST case ALCH-B26Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.4 years (23,531 days).
Specimen ALCH-B26Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file edf4705a-dcea-46e7-a722-825647db6c69.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B26Q-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/314cf1fb-9a21-4ed6-bb78-eb27d0827b00

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 16,703; copy number 2: 38,768; copy number 3: 2,685; copy number 4: 209.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,370,448–75,590,649, 12 genes: OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1.
- chr9:136,494,433–136,546,048, 3 genes (within-gene range 0–1): NOTCH1, MIR4673, AL592301.1.
- chr12:132,489,551–132,610,582, 6 genes: FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1, LRCOL1.
- chr18:59,220,158–59,230,774, 1 gene: GRP.
- chr19:984,332–1,039,068, 8 genes: WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1.
- chr22:18,533,646–18,611,919, 4 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 16,703. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
